Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A7NH, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A7NH-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: PROSTATE, LAPAROSCOPIC ROBOTIC ASSISTED PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE: 3+4=7.
- B. MICROSCOPIC GLEASON PATTERN 5 CARCINOMA IS IDENTIFIED AND CONSTITUTES APPROXIMATELY 2% OF THE TOTAL TUMOR VOLUME.
- C. THE CARCINOMA MEASURES 1.2 CM IN GREATEST NODULAR DIMENSION.
- D. THE CARCINOMA IS MULTIFOCAL, INVOLVES BOTH THE RIGHT AND THE LEFT LOBES OF THE PROSTATE, AND CONSTITUTES APPROXIMATELY 5-10% OF THE TOTAL PROSTATE VOLUME ASSESSED.
- E. THE CARCINOMA IS CONFINED WITHIN THE CAPSULE OF THE PROSTATE.
- F. ALL INKED MARGINS OF RESECTION ARE FREE OF TUMOR.
- G. BILATERAL SEMINAL VESICLES, NO EVIDENCE OF CARCINOMA SEEN.
- H. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
- I. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS SEEN.
- J. TNM STAGE: T2c N0 MX.
- K. HISTOLOGIC GRADE: G3 (POORLY DIFFERENTIATED).

PART 2: LYMPH NODES, BILATERAL PELVIC, LYMPHADENECTOMY -

FOUR (4) LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA SEEN (0/4).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 4.9
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 40%
WEIGHT OF PROSTATE: 40.52gm
TUMOR SIZE: Maximum dimension: 1.2 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 4
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2c
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

CLF ICD-O-3
Adenocarcinoma, acinar
path 8140/3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
QW 9/24/13

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Prostate adenocarcinoma -	Age:	N/A
	(Prostate adenocarcinoma)	Date of Birth:	
Event:	PathDiscrepancy	Sex:	M
Interviewer:			

Tumor Identifier Provided on Initial Case Quality Control Form		Provide the tumor identifier documented on the initial case quality control form for this case.
Pathologic Diagnosis Provided on Initial Pathology Report	prostate adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF	acinar type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	sample submitted was 4+3	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file e186cce5-98ae-4876-b6bb-9ab327950497 (TCGA-EJ-A7NH.87E5A9C3-9C6F-4452-9D52-FAD4F7FC66C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).